Somatic mutation profile of tumor specimen TARGET-20-PATLBC-03A (aliquot TARGET-20-PATLBC-03A-01D) from TARGET case TARGET-20-PATLBC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,091 days).
Specimen TARGET-20-PATLBC-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 787ee367-ec94-48ca-a0fe-73715ed4977c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATLBC-14A (Bone Marrow Normal), aliquot TARGET-20-PATLBC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5e186e3-1b5d-4c48-a99a-a793ca6a245e

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 12/182 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 52/174 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.1940dup p.G649Wfs*9 | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | catalogued as COSV60102566, COSV60117493; called by mutect2, pindel, varscan2
- ASXL2 | c.1812dup p.L605Sfs*3 | Frame Shift Ins (INS) | VAF 41/156 reads (26%) | called by mutect2, pindel, varscan2
- NCOR1 | c.2493_2494insAGCCCCA p.H832Sfs*6 | Frame Shift Ins (INS) | VAF 42/282 reads (15%) | called by mutect2, pindel, varscan2
